FM case AD152 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/e382f9f4-fd32-4e9b-a6dc-82c126cd623e

Male, 85.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the bladder; primary biopsied or resected from the bladder. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
